Gene-level copy-number profile of tumor specimen TCGA-86-8280-01A from TCGA case TCGA-86-8280, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Bronchiolo-alveolar carcinoma, non-mucinous; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IIA; Age at diagnosis: 54.7 years (19,977 days).
Specimen TCGA-86-8280-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUAD.842ebc0b-723a-471e-82d3-2146b53885ec.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-86-8280-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 805 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/1446f615-9d46-4fe9-85e3-f179b4c60a3d

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 49; copy number 1: 4,292; copy number 2: 31,185; copy number 3: 16,364; copy number 4: 5,912; copy number 5: 2,016.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-86-8280-01A-11D-2283-01): tumor purity 0.45, ploidy 2.56, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 49 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:21,239,002–23,826,337, 49 genes (within-gene range 0–1): IFNA14, IFNA22P, IFNA5, IFNA20P, KLHL9, IFNA6, IFNA13, IFNA2, AL353732.1, IFNA11P, IFNA12P, IFNA8, AL353732.2, IFNWP2, IFNA1, MIR31HG, IFNWP19, IFNE, MIR31, SNORD39, H3P30, KHSRPP1, RN7SL151P, MTAP, AL359922.1, TUBB8P1, AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2, AL157937.1, DMRTA1, LINC01239, AL391117.1, CLIC4P1, AC017067.1, AL357614.1, AL445623.2, SUMO2P2, AL445623.1, NOP56P2, ELAVL2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 2,016 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:62,275,361–159,233,377, 1,936 genes, copy number 5 (broad region; genes not listed).
- chr14:30,370,108–32,882,830, 53 genes, copy number 5: AL079305.1, G2E3-AS1, AL117355.1, SYF2P1, G2E3, SCFD1, UBE2CP1, AL121852.1, RPL12P5, AL049830.2, AL049830.1, COCH, AL049830.3, STRN3, HIGD1AP17, MIR624, AL049830.4, AP4S1, HECTD1, RPL21P5, RNU6-541P, Y_RNA, AL136418.1, Y_RNA, HEATR5A, ATP5MC1P2, AL139353.1, AL139353.2, DTD2, AL163973.1, GPR33, NUBPL, AL163973.3, AL163973.2, RNU6-602P, RNU6-455P, AL355112.1, LINC02313, AL352984.2, AL352984.1, ARHGAP5-AS1, ARHGAP5, AL161665.1, AL161665.2, RNU6-7, RNU6-8, AL136298.2, KIAA1143P1, AKAP6, AL136298.1, RN7SL660P, MTCO1P2, AL049781.1.
- chr14:38,190,983–39,432,500, 27 genes, copy number 5: AL392023.1, SSTR1, CLEC14A, AL355835.1, AL357094.1, KRT8P1, LINC00639, AL132994.1, AL132994.2, Y_RNA, SEC23A, AL109628.1, SEC23A-AS1, PPIAP4, GEMIN2, TRAPPC6B, AL109628.2, RPL7AP2, AL132639.3, PNN, AL132639.1, YTHDF2P1, MIA2, AL132639.2, GLRX5P3, COILP1, FBXO33.

Autosomal genes at a single copy (total copy number 1): 4,292. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
